Somatic mutation profile of tumor specimen TCGA-A4-A5DU-01A (aliquot TCGA-A4-A5DU-01A-11D-A28G-10) from TCGA case TCGA-A4-A5DU, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 45.9 years (16,779 days).
Specimen TCGA-A4-A5DU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5df62510-c944-4dd0-b0e9-6f2951901ed7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A5DU-10A (Blood Derived Normal), aliquot TCGA-A4-A5DU-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3ef788b-9fae-488d-8f09-ff07578c6be8

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 24, Silent 5, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.2881C>G p.P961A (on ENST00000272895 / NM_173076.3; = p.P643A on NM_015657.3) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55968924, COSV99791111; called by muse, mutect2, varscan2
- BAG6 | c.1371T>A p.D457E | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.716); catalogued as COSV52993327; called by muse, mutect2, varscan2
- CC2D2A | c.2293A>G p.S765G | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67504896; called by muse, mutect2, varscan2
- CDC37 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1229289732, COSV55767745; called by muse, mutect2, varscan2
- CEMIP | c.869-2A>T p.X290_splice | Splice Site (SNP) | VAF 25/48 reads (52%) | catalogued as COSV54997249; called by muse, mutect2, varscan2
- DDX50 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV65293005; called by muse, mutect2, varscan2
- FASLG | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs111238176, COSV60680590; called by muse, mutect2, varscan2
- GLTPD2 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58702817; called by muse, mutect2, varscan2
- IL6ST | c.2030A>T p.N677I | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV61142286; called by muse, mutect2, varscan2
- INCENP | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1371442439, COSV53918967; called by muse, mutect2
- KDM6B | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as rs1422895520, COSV54684575; called by muse, mutect2
- NISCH | c.4028C>T p.P1343L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs369447186; called by muse, mutect2, varscan2
- PDE2A | c.1819C>A p.P607T | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57810944; called by muse, mutect2, varscan2
- PDP1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as COSV52602978; called by muse, mutect2, varscan2
- PIGR | c.322T>C p.Y108H | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62904652; called by muse, mutect2, varscan2
- PON2 | c.478C>A p.H160N | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56002979; called by muse, mutect2, varscan2
- PRKCE | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60325117; called by muse, mutect2, varscan2
- RORC | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757895511, COSV59094574; called by muse, mutect2, varscan2
- SLC25A3 | c.1078T>A p.L360I (on ENST00000228318 / NM_005888.3; = p.L359I on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.19); catalogued as COSV51846802; called by muse, mutect2, varscan2
- SLC5A12 | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54823449; called by muse, mutect2, varscan2
- SZT2 | c.6151C>T p.R2051C (on ENST00000634258 / NM_001365999.1; = p.R1994C on NM_015284.4) | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534888615, COSV65167348; called by muse, mutect2, varscan2
- TAS1R1 | c.2515G>A p.G839S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1320135260, COSV59840320; called by muse, mutect2, varscan2
- TNS1 | c.1296G>C p.L432F | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV50735304; called by muse, mutect2, varscan2
- ZMIZ2 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54809903; called by muse, mutect2, varscan2
- ZNF721 | c.1419_1421del p.S475del (on ENST00000338977; = p.S487del on NM_133474.4) | In Frame Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs782142616; called by mutect2, pindel, varscan2
- DISC1 | c.1653del p.K551Nfs*16 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); called by muse, mutect2
- TRIM25 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 120/209 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.063); called by mutect2, varscan2
- ACO2 | c.810T>C p.P270= | Silent (SNP) | VAF 64/117 reads (55%) | catalogued as COSV53444377; called by muse, mutect2, varscan2
- AUTS2 | c.1341C>G p.T447= | Silent (SNP) | VAF 111/203 reads (55%) | catalogued as COSV61420205, COSV61422524; called by muse, mutect2, varscan2
- FHL5 | c.108A>G p.V36= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV58735627, COSV58739291; called by muse, mutect2
- PPM1B | c.1314T>C p.S438= | Silent (SNP) | VAF 124/187 reads (66%) | catalogued as COSV56768539; called by muse, mutect2, varscan2
- RPGRIP1 | c.2022C>T p.P674= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV52853977; called by muse, mutect2, varscan2
